Somatic mutation profile of tumor specimen ER-AC8A-TTM1-A (aliquot ER-AC8A-TTM1-A-1-0-D-A49A-34) from EXCEPTIONAL_RESPONDERS case ER-AC8A, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Large cell neuroendocrine carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 47.8 years (17,459 days).
Specimen ER-AC8A-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46218cb0-72ea-407d-bdfc-8894383dd88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AC8A-NT1-A (Solid Tissue Normal), aliquot ER-AC8A-NT1-A-1-0-D-A49A-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99e27a1e-bf8c-43e3-ba91-53b90e92c9a2

The open-access MAF lists 377 somatic variants for this specimen: 274 protein-altering or splice-affecting, 75 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 75, Nonsense Mutation 25, Frame Shift Del 11, 3'UTR 11, Splice Region 7, Intron 6, 3'Flank 4, 5'UTR 3, RNA 3, Splice Site 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs368584197, COSV61358168; called by muse, mutect2, varscan2
- ADARB1 | c.2121G>T p.E707D (on ENST00000360697 / NM_001346687.2; = p.E667D on NM_001112.4) | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV62344941; called by muse, mutect2
- AFF3 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100417689; called by muse, mutect2, varscan2
- ALKBH5 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV67687219; called by muse, mutect2, varscan2
- ALMS1 | c.8029G>T p.D2677Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100044081; called by muse, mutect2, varscan2
- APOB | c.12038T>C p.M4013T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs144922840, CD076729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP36 | c.471G>T p.R157S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.916); catalogued as COSV52273920; called by muse, mutect2, varscan2
- ARHGAP5 | c.4252A>T p.M1418L (on ENST00000345122 / NM_001030055.2; = p.M1417L on NM_001173.3) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.627); catalogued as rs747614494, COSV53734998; called by mutect2, varscan2
- ATG13 | c.1076G>T p.R359L (on ENST00000359513 / NM_001346321.1; = p.R322L on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV56321446; called by muse, mutect2, varscan2
- BICD1 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV55688073, COSV55688385; called by muse, mutect2, varscan2
- CLCA1 | c.1843C>A p.R615S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as COSV52326014; called by muse, mutect2, varscan2
- CNNM1 | c.1121A>T p.Y374F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs1053980016; called by muse, mutect2, varscan2
- CUL4B | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60684776; called by muse, mutect2, varscan2
- CYP2C18 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs550117143, COSV53671254; called by mutect2, varscan2
- DCLRE1B | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs770126449, COSV65812891; called by muse, mutect2, varscan2
- DDX58 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371685816; called by muse, mutect2, varscan2
- DNAH3 | c.6634A>G p.I2212V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs1343099564; called by muse, mutect2, varscan2
- DNAH5 | c.1106C>A p.A369D | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as rs1437341884; called by muse, mutect2, varscan2
- DPH2 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99356197; called by muse, mutect2, varscan2
- EPS8 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs906383973; called by muse, mutect2, varscan2
- EVC2 | c.941G>T p.W314L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60390774; called by muse, mutect2
- EYS | c.5429T>C p.M1810T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1478819516; called by muse, mutect2, varscan2
- FOXG1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs767463607, COSV57398427; called by muse, mutect2, varscan2
- FREM1 | c.1979A>G p.Y660C | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs905746165; called by muse, varscan2
- GNAI1 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63522362; called by muse, varscan2
- GOLGB1 | c.8892G>C p.R2964S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV100510470; called by muse, mutect2, varscan2
- GPC5 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV65585464; called by muse, mutect2, varscan2
- HBD | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53083971; called by muse, mutect2, varscan2
- HELZ2 | c.7925G>A p.C2642Y (on ENST00000467148 / NM_001037335.2; = p.C2073Y on NM_033405.3) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs768772158; called by muse, mutect2, varscan2
- HEPH | c.3397C>A p.Q1133K (on ENST00000343002; = p.Q866K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.066); catalogued as COSV100294812; called by muse, mutect2, varscan2
- ITGA1 | c.2779G>T p.E927* | Nonsense Mutation (SNP) | VAF 16/214 reads (7%) | catalogued as COSV50896647; called by muse, mutect2
- ITPRIP | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs760053554, COSV53390563, COSV53391516; called by muse, mutect2, varscan2
- KIF21A | c.4402G>T p.A1468S (on ENST00000361418 / NM_001378440.1; = p.A1455S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as COSV100735228; called by muse, mutect2, varscan2
- KMT2B | c.3509G>T p.R1170L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99718516; called by muse, mutect2, varscan2
- LCE3D | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV100909862, COSV100909869; called by muse, mutect2, varscan2
- LILRB2 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1212091770; called by muse, mutect2
- LRP1B | c.9283G>A p.D3095N | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67195375; called by muse, mutect2, varscan2
- LY75 | c.926C>A p.A309E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.511); catalogued as COSV55105273; called by muse, mutect2, varscan2
- MAPKBP1 | c.2249G>T p.R750L (on ENST00000456763 / NM_001128608.2; = p.R744L on NM_014994.3) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV52958620; called by muse, mutect2, varscan2
- MARCO | c.426G>T p.G142= | Splice Region (SNP) | VAF 5/51 reads (10%) | catalogued as COSV59054463; called by muse, mutect2
- MEGF8 | c.5068G>C p.G1690R (on ENST00000251268 / NM_001271938.2; = p.G1623R on NM_001410.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416418731; called by muse, mutect2, varscan2
- MSH4 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV54210885; called by muse, mutect2, varscan2
- MUC16 | c.36823G>A p.V12275I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.027); catalogued as rs1434280034; called by muse, mutect2, varscan2
- NBAS | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1280023379, COSV55735166; called by muse, mutect2, varscan2
- NBEA | c.4822A>G p.T1608A | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs372216603; called by muse, mutect2, varscan2
- NCKAP1 | c.3223A>T p.K1075* | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as COSV62940565; called by muse, mutect2, varscan2
- NLRP4 | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as rs752623697; called by muse, mutect2, varscan2
- NVL | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as rs138668303; called by muse, mutect2, varscan2
- OBSCN | c.14299C>T p.R4767C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs369823285; called by muse, mutect2, varscan2
- OPA1 | c.770A>G p.Y257C (on ENST00000361510 / NM_130837.3; = p.Y221C on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as COSV100655406; called by muse, mutect2, varscan2
- OR2L13 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV63551845; called by muse, mutect2, varscan2
- OR5W2 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV60614558; called by muse, mutect2, varscan2
- PCED1B | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71395453; called by muse, mutect2, varscan2
- PHKB | c.2994C>G p.I998M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV54517366, COSV54518228; called by muse, mutect2, varscan2
- PKHD1L1 | c.10561A>G p.I3521V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs889144634, COSV65744511; called by muse, mutect2, varscan2
- PKLR | c.398A>T p.N133I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770337533, COSV61361743; called by muse, mutect2, varscan2
- POLR2I | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs1345596180; called by muse, mutect2, varscan2
- PPP2R2C | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV59442406; called by muse, mutect2, varscan2
- PRKDC | c.3262G>T p.E1088* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs1432931768, COSV58054825; called by muse, mutect2, varscan2
- PSKH2 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52612272; called by muse, mutect2, varscan2
- PTPN9 | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60723965; called by muse, mutect2, varscan2
- QSOX1 | c.1449G>T p.R483S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100852839; called by muse, mutect2, varscan2
- RB1 | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as CD040611, COSV57295141, COSV57300560; called by muse, mutect2, varscan2
- RFLNA | c.434C>A p.T145K (on ENST00000546355 / NM_001365156.1; = p.T64K on NM_181709.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs528216610, COSV58038073; called by muse, mutect2, varscan2
- RFX6 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1275582717, CD105742; called by muse, mutect2, varscan2
- RORC | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59093600; called by muse, mutect2, varscan2
- RREB1 | c.4180G>T p.A1394S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as rs754168034; called by muse, mutect2, varscan2
- RYR2 | c.8704G>C p.A2902P | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63711912; called by muse, mutect2, varscan2
- SEMA3E | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100318451; called by muse, mutect2, varscan2
- SERPINI2 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 41/148 reads (28%) | catalogued as COSV52985078; called by mutect2, varscan2
- SH2B1 | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59467300; called by muse, mutect2, varscan2
- SHISA7 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs756255333, COSV66244985; called by muse, mutect2
- SLC25A32 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1322976701; called by muse, mutect2, varscan2
- SLC5A8 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73311275; called by muse, mutect2, varscan2
- SLC8A3 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs545903398; called by muse, mutect2, varscan2
- TREML2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1199438193; called by muse, mutect2
- TSC2 | c.4949A>G p.Y1650C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs45501091, CM981957, COSV99032338; ClinVar: drug response / not provided; called by muse, mutect2, varscan2
- UPK1B | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51769315; called by muse, mutect2, varscan2
- ZNF347 | c.980G>T p.S327I | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV61968592; called by muse, mutect2, varscan2
- ZNF365 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67926472; called by muse, mutect2, varscan2
- ZNF532 | c.2688C>G p.I896M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60173221; called by muse, mutect2, varscan2
- ZNF610 | c.629del p.G210Vfs*15 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | catalogued as COSV58344937; called by mutect2, pindel, varscan2
- ZXDC | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60448832; called by muse, mutect2, varscan2
- ABCC5 | c.516G>C p.W172C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ABCG2 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABLIM1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ADGB | c.4614G>T p.M1538I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG4 | c.7733T>A p.M2578K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ADGRG7 | c.2291G>C p.R764T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- AHCTF1 | c.3142A>G p.I1048V (on ENST00000366508; = p.I1022V on NM_015446.5) | Missense Mutation (SNP) | VAF 79/354 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AK5 | c.929A>T p.D310V (on ENST00000354567 / NM_174858.3; = p.D284V on NM_012093.4) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALPK2 | c.4541A>C p.Q1514P | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- APPL2 | c.1938A>T p.Q646H | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMCX1 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ATAD3B | c.753dup p.K252Efs*40 (on ENST00000308647; = p.K358Efs*40 on NM_031921.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- ATG4A | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- ATM | c.1999A>T p.R667* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- ATR | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- AXL | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- C10orf71 | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CACNA1E | c.2698G>C p.G900R | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1S | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CAMP | c.62T>C p.L21P (on ENST00000296435; = p.L18P on NM_004345.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.16913A>T p.N5638I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CD72 | c.719A>G p.H240R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CEBPE | c.773A>T p.D258V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- CENPA | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CHAF1A | c.1431G>T p.M477I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNB3 | c.360T>A p.N120K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIAO3 | c.19G>T p.G7W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCA3P | n.466G>A | Splice Region (SNP) | VAF 43/159 reads (27%) | called by muse, mutect2, varscan2
- CNBP | c.164A>T p.Y55F | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- COL1A2 | c.3599G>A p.G1200D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- COL4A6 | c.3443G>T p.G1148V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.6241G>A p.V2081I (on ENST00000312481; = p.V2077I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CPA6 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CSMD3 | c.8285T>A p.L2762Q (on ENST00000297405 / NM_001363185.1; = p.L2593Q on NM_052900.3) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CST9LP1 | n.352A>G | Splice Region (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- CT47B1 | c.636del p.E213Rfs*81 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- CTSV | c.213T>G p.H71Q | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CYP2C18 | c.272del p.G91Efs*39 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel, varscan2
- DDX60L | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DGKB | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- DISP3 | c.402del p.R135Gfs*92 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- DLX6 | c.765G>C p.W255C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.5134G>T p.G1712C (on ENST00000445597; = p.G2117C on NM_001367479.1) | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DNAH17 | c.11939C>G p.P3980R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNTTIP1 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DPP6 | c.2099A>G p.Y700C (on ENST00000377770 / NM_001364500.2; = p.Y638C on NM_001936.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- E2F5 | c.461T>A p.L154Q | Missense Mutation (SNP) | VAF 33/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- EBF2 | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ELFN2 | c.2383A>T p.K795* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- ENOX2 | c.296A>C p.E99A (on ENST00000338144 / NM_001382520.1; = p.E70A on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPHB1 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHX4 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- ERCC8 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ERO1B | c.359T>G p.M120R | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM122C | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- FAM135B | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- FAT3 | c.2945G>T p.R982I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- FATE1 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG2 | c.6863C>A p.S2288Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FRMPD1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- FRYL | c.6593A>T p.Q2198L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FRYL | c.1651A>G p.K551E | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRA2 | c.1059+1G>T p.X353_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- GAK | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GAL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GAL | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GBF1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GDI1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GLP2R | c.1423G>T p.G475* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- GLUD1 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GNAI1 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, varscan2
- GPR15 | c.870G>T p.L290F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.291); called by muse, mutect2
- GPR15 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GRIA3 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- HAUS7 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HRH4 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ICE1 | c.3982G>T p.E1328* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- IGF1R | c.1299C>A p.D433E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- IGSF1 | c.2544C>A p.S848R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- IGSF9B | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- IL4I1 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRF2BPL | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.736); called by muse, mutect2
- KCNE2 | c.276G>A p.W92* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- KCNT1 | c.2310C>G p.S770R (on ENST00000488444; = p.S789R on NM_020822.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- KRTAP19-5 | c.19T>A p.Y7N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- LRFN5 | c.1188T>A p.D396E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LRRC63 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LRRK2 | c.6046G>T p.A2016S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LSAMP | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MAGEA12 | c.74T>A p.L25* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- MAGI1 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MAJIN | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MAP3K21 | c.1926G>T p.G642= | Splice Region (SNP) | VAF 41/186 reads (22%) | called by muse, mutect2, varscan2
- MCF2 | c.1673+1G>C p.X558_splice | Splice Site (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- MN1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.586); called by mutect2, varscan2
- MOS | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MRE11 | c.96_97del p.G33Kfs*2 | Frame Shift Del (DEL) | VAF 42/170 reads (25%) | called by pindel, varscan2
- MYRIP | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- NHEJ1 | c.253A>T p.K85* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- NLRP4 | c.2116C>A p.L706I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- NOM1 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- NOTCH1 | c.3693_3700del p.V1232Efs*6 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by pindel, varscan2
- NUP160 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OLFM1 | c.81del p.S28Rfs*67 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- OR10K1 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T2 | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.05); called by muse, mutect2
- OR52E2 | c.878A>T p.Y293F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5D16 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OR6K3 | c.691C>A p.L231M (on ENST00000368146; = p.L215M on NM_001005327.2) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- OR6P1 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR8K5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAQR9 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAWR | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- PCARE | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB3 | c.1624A>T p.S542C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCED1A | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PCK1 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCOLCE2 | c.1181G>T p.S394I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PDE3B | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- PFKFB1 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PIK3CG | c.2108T>A p.I703K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PIM2 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.10097A>T p.H3366L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PLPPR4 | c.1635C>A p.S545R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- POLR1B | c.1613-4C>T | Splice Region (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- POLR2C | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PPDPF | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PPFIA2 | c.2007A>T p.E669D | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPP2R3A | c.2724G>C p.W908C | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP6R1 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PRND | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRR16 | c.742G>A p.G248S (on ENST00000407149 / NM_001300783.2; = p.G225S on NM_016644.2) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PRR23A | c.682A>G p.S228G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, varscan2
- PZP | c.1724del p.P575Qfs*9 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- QKI | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGEF1C | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SCN11A | c.4357G>T p.E1453* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SCN11A | c.4356G>T p.Q1452H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- SCN3A | c.1674T>A p.S558= | Splice Region (SNP) | VAF 126/338 reads (37%) | called by muse, mutect2, varscan2
- SCN7A | c.822T>A p.N274K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SEPTIN4 | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SERPINB5 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SIGLEC12 | c.1453G>T p.A485S (on ENST00000291707 / NM_053003.4; = p.A367S on NM_033329.2) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SIRT1 | c.792G>T p.V264= | Splice Region (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- SLC13A3 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A8 | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT2 | c.4467del p.Q1490Sfs*6 | Frame Shift Del (DEL) | VAF 70/263 reads (27%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.2551G>T p.G851W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMCO2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SMYD1 | c.1251del p.C417* | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- SRRT | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- STAG1 | c.3294G>C p.W1098C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SUFU | c.37_53del p.T13Wfs*29 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- SYNE2 | c.6862A>T p.K2288* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | called by muse, varscan2
- TAAR9 | c.574G>C p.A192P | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TENM4 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TERT | c.2993G>T p.C998F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TET1 | c.3997A>G p.R1333G | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- THSD7A | c.4829G>T p.G1610V | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THSD7A | c.3569C>G p.S1190* | Nonsense Mutation (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2, varscan2
- TLE3 | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM52B | c.178C>A p.L60M (on ENST00000381923 / NM_001079815.1; = p.L40M on NM_153022.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMEM67 | c.1089G>T p.R363S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TRERF1 | c.1701_1706del p.P569_P570del | In Frame Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- TRPM2 | c.98T>A p.L33H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TUBA3D | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TUBB | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- UBE2O | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE3D | c.731T>A p.I244K | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- USH2A | c.14160A>T p.K4720N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- UTP18 | c.821C>G p.A274G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VN1R4 | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VNN2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- VPS13C | c.1175T>A p.M392K (on ENST00000644861 / NM_020821.3; = p.M349K on NM_017684.5) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- VWDE | c.2423C>A p.T808N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- WASL | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WDR86 | c.299T>A p.V100E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNT5B | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZCCHC7 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ZEB2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF160 | c.1912A>T p.T638S | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF18 | c.1157G>A p.W386* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- ZNF407 | c.4353G>T p.K1451N | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF431 | c.1591A>T p.R531W | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZNF664 | c.571A>T p.R191* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- ZNF75D | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- ZNF791 | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF862 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZSWIM3 | c.1226A>T p.Q409L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ABCB1 | c.1341A>G p.T447= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV55947365; called by muse, mutect2, varscan2
- ACACA | c.3108A>G p.T1036= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2259G>A p.L753= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV61279978; called by muse, mutect2, varscan2
- ALDH1B1 | c.294C>T p.A98= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1186580746; called by muse, mutect2, varscan2
- ALMS1 | c.279C>T p.P93= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs770203539; called by muse, mutect2, varscan2
- APCDD1L | c.315C>A p.L105= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.630A>G p.K210= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2676C>A p.I892= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- BLZF1 | c.822C>T p.S274= | Silent (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
- CARD11 | c.906G>A p.L302= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- CATSPERB | c.492G>T p.G164= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- CFAP70 | c.1263T>C p.D421= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- CHIT1 | c.1302G>T p.R434= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs912206800, COSV55148930; called by mutect2, varscan2
- DCAF8L2 | c.492G>T p.S164= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs776836322; called by muse, mutect2, varscan2
- DENND4A | c.4026C>T p.T1342= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV101475285; called by muse, mutect2, varscan2
- DLK1 | c.1002G>T p.V334= | Silent (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- DMBT1 | c.771C>A p.T257= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV57560783; called by muse, mutect2, varscan2
- DNAH12 | c.3168T>A p.I1056= (on ENST00000351747; = p.I1079= on NM_001366028.2) | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- DOC2A | c.681G>A p.A227= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs769227502, COSV58750545; called by muse, mutect2, varscan2
- DSCAML1 | c.1284C>T p.N428= (on ENST00000321322; = p.N368= on NM_020693.4) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs539473354, COSV58384782; called by muse, mutect2, varscan2
- EPHA3 | c.708G>A p.E236= | Silent (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- FANCM | c.2958A>C p.V986= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs779452715; called by muse, mutect2, varscan2
- FZD2 | c.1633C>T p.L545= | Silent (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- GABRB3 | c.1341C>T p.A447= | Silent (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GABRR3 | c.1251C>T p.T417= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs772294883, COSV101512338, COSV72115976; called by muse, varscan2
- HAUS7 | c.549C>T p.H183= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1556982274; called by muse, mutect2, varscan2
- HTR1F | c.390G>A p.E130= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1400728171; called by muse, mutect2, varscan2
- ITPR1 | c.5814C>T p.D1938= (on ENST00000354582; = p.D1883= on NM_002222.7) | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs755937487; called by muse, mutect2, varscan2
- JPH4 | c.1572G>A p.G524= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58115241; called by muse, mutect2, varscan2
- KAT6B | c.159C>T p.L53= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs764014758, COSV54742748; called by muse, mutect2, varscan2
- KCNH5 | c.324T>C p.Y108= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- KCTD2 | c.759G>T p.A253= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- LRP2 | c.8217C>T p.H2739= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- LRRTM4 | c.786G>T p.G262= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- MAK | c.1203C>T p.F401= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- MAP1S | c.3159G>T p.P1053= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- MIA2 | c.2334T>C p.G778= | Silent (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- MOAP1 | c.582G>T p.A194= | Silent (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- MRPS35 | c.15G>T p.A5= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.33945A>T p.I11315= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- MUC19 | c.1461A>T p.A487= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- MYO1G | c.1368G>C p.L456= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, varscan2
- NKIRAS2 | c.189G>T p.R63= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- NRIP1 | c.63A>G p.L21= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- NRK | c.2166C>A p.A722= | Silent (SNP) | VAF 38/202 reads (19%) | called by mutect2, varscan2
- OR1D2 | c.816A>C p.V272= | Silent (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- OR52L1 | c.699T>G p.G233= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- OR9G1 | c.912C>T p.L304= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- P2RX5 | c.426A>T p.T142= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- PAQR9 | c.183G>C p.S61= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- PDIA4 | c.879G>T p.L293= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- PLXNB1 | c.2454G>T p.L818= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs567986104; called by muse, mutect2, varscan2
- POMK | c.522G>T p.T174= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PTPRN | c.2301C>A p.A767= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- RGS18 | c.510C>A p.L170= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV100817775; called by muse, mutect2, varscan2
- RYR2 | c.11421A>G p.A3807= | Silent (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- RYR3 | c.5997G>A p.A1999= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs142550033, COSV101213239, COSV66784909; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETBP1 | c.3240A>G p.G1080= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.627C>A p.T209= | Silent (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- SLC17A6 | c.939T>C p.Y313= | Silent (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.1467C>T p.P489= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV56872230; called by muse, mutect2, varscan2
- SPAM1 | c.643T>C p.L215= | Silent (SNP) | VAF 48/162 reads (30%) | called by muse, mutect2, varscan2
- STAU2 | c.1500G>T p.L500= (on ENST00000524300 / NM_001164380.2; = p.L468= on NM_014393.2) | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV100869282; called by muse, mutect2, varscan2
- STAU2 | c.138T>C p.L46= (on ENST00000524300 / NM_001164380.2; = p.L14= on NM_014393.2) | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- TASP1 | c.397C>T p.L133= | Silent (SNP) | VAF 44/193 reads (23%) | called by muse, mutect2, varscan2
- TMEM132C | c.2334C>A p.A778= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- TMTC1 | c.378T>C p.T126= (on ENST00000539277 / NM_001193451.2; = p.T18= on NM_175861.3) | Silent (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- TROAP | c.1689G>A p.E563= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.60837C>T p.T20279= (on ENST00000591111; = p.T12855= on NM_003319.4) | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs753720118; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.11922C>A p.V3974= (on ENST00000591111; = p.V3928= on NM_003319.4) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100628675, COSV60062006; called by muse, mutect2, varscan2
- USH2A | c.6102T>A p.A2034= | Silent (SNP) | VAF 59/173 reads (34%) | called by muse, mutect2, varscan2
- UTP18 | c.180G>C p.A60= | Silent (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- VIT | c.1128C>A p.I376= (on ENST00000389975 / NM_001177969.1; = p.I391= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- ZNF692 | c.1182C>T p.C394= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs377070155; called by muse, mutect2, varscan2
- ZSCAN23 | c.885C>T p.H295= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- AC099552.1 | n.257C>T | RNA (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- AMER3 | c.*3226G>A | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- ATP1A3 | c.3052+135G>T | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- BACE2 | c.312+14085G>A | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- BHLHA9 | c.*168G>T | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- CCDC178 | c.*1G>T | 3'UTR (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- CCDC190 | chr1:162853120 C>G | 3'Flank (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- COLCA2 | chr11:111296337 T>C | 5'Flank (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- CTRL | c.52+19G>T | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.-79C>A | 5'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- DET1 | c.-10-4637A>T | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- FZD1 | c.*843C>T | 3'UTR (SNP) | VAF 5/70 reads (7%) | catalogued as rs903653463; called by muse, mutect2
- GUK1 | c.113-11C>T | Intron (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100451727; called by muse, mutect2, varscan2
- HNRNPCL2 | c.-36T>A | 5'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- IL9R | chrX:156015492 G>T | 3'Flank (SNP) | VAF 4/48 reads (8%) | called by muse, varscan2
- ISCA1P1 | n.3G>A | RNA (SNP) | VAF 25/139 reads (18%) | catalogued as rs1039880694; called by muse, mutect2, varscan2
- KCNA1 | c.*2906C>A | 3'UTR (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- KCNC2 | c.*723G>C | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+2488G>T | Intron (SNP) | VAF 43/327 reads (13%) | catalogued as rs749536246; called by muse, mutect2, varscan2
- MAGEA3 | c.*298G>T | 3'UTR (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- REG1A | c.*8T>A | 3'UTR (SNP) | VAF 7/55 reads (13%) | catalogued as rs1254394276; called by muse, mutect2, varscan2
- SPRY3 | c.*4718G>T | 3'UTR (SNP) | VAF 55/210 reads (26%) | catalogued as rs1015038885; called by muse, mutect2, varscan2
- TAOK2 | chr16:29989604 G>A | 3'Flank (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- TATDN3 | c.-16_-1del | 5'UTR (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- TMPRSS11BNL | n.433T>C | RNA (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- TMSB15A | c.*6G>T | 3'UTR (SNP) | VAF 16/285 reads (6%) | called by muse, mutect2
- ZNF493 | chr19:21427335 A>T | 3'Flank (SNP) | VAF 4/34 reads (12%) | catalogued as rs919340520; called by muse, mutect2
- ZNF574 | c.*82G>T | 3'UTR (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
